NCICCR case DLBCL10923 — Genomic Variation in Diffuse Large B Cell Lymphomas (NCICCR-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/44e4d463-5453-4fae-830f-1e9eb238da7d

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph node, NOS; Age at diagnosis: 45.0 years (16,425 days); Ann Arbor clinical stage: Stage IV; International Prognostic Index (IPI): Low-Intermediate Risk.

Biospecimens (1 sample)
- Sample DLBCL10923-sample: Sample type: Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Lymphocytes; Preservation method: Frozen.
